Surgical pathology report (de-identified scan), TCGA case TCGA-4X-A9F9, project TCGA-THYM (Thymoma), tissue source site Yale University, specimen TCGA-4X-A9F9-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient
MR #
DOB/Age/Sex
Visit #:
Submitting Physician:

Accession #:
Taken:
Accessioned:
Adm-Disch Date:
Reported:

Clinical History and Impression:

Preop dx: Thymoma
Procedure: Sternotomy, thymectomy

Specimen(s) Received:
THYMUS

FINAL DIAGNOSIS

THYMUS, PLEURA, PERICARDIUM AND LUNG, RADICAL THYMECTOMY:

- THYMOMA, WHO TYPE B1, WITH INVASION INTO LUNG PARENCHYMA (6 CM)
- ANTERIOR MEDIASTINAL PLEURAL MARGIN FOCALLY INVOLVED
- pT3, Nx, Mx stage III (MODIFIED MASAOKA STAGE)

NOTE: Section from block 6 shows tumor both inked and cauterized. Keratin stain supports interpretation as epithelial cells are present at cauterized margin. Tumor also extends to left anterior and posterior surgical margins but per surgeon, these are not of clinical significance. Tumor does not involve lung margin, pericardium, innominate vein or phrenic nerve margin as indicated by surgeon. See also synoptic summary

SYNOPTIC SUMMARY

Specimen: Thymus and other: Pleura, lung, pericardium, innominate vein
Procedure: Thymectomy
Specimen Integrity: Intact
Tumor Size: 6 cm
+ Additional dimensions: 5 x 2 cm
Histologic Type: Type B1 thymoma
Tumor Extension: Pulmonary parenchyma, pleura (mediastinal)
Margins: Anterior margin positive
Treatment Effect: Not applicable
Lymph-Vascular invasion: Not identified
Regional Lymph Nodes: Cannot be assessed
Pathologic Staging for Thymomas: Stage III: Macroscopic invasion of neighboring organs
Implants/Distant Metastasis: Cannot be assessed
Pathologic Staging for Thymic Carcinomas (pTNM):
Primary Tumor (pT):

10003
Thymoma, Type B1,
malignant 8583/1
Site: Thymus 137.9
J 6/24/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

pT3: Tumor invades neighboring structures, such as pericardium, mediastinal pleura, thoracic wall, great vessels, and lung

Regional Lymph Nodes (pN):

pNX: Regional lymph nodes cannot be assessed

Distant Metastasis (pM):

Not applicable

*Additional Pathologic Findings: Other: Lymphoid follicular hyperplasia

Pathologist:

*** Report Electronically Signed Out ***

This electronic signature indicates that the pathologist has personally reviewed the available gross and/or microscopic material and has based the diagnosis on that evaluation.

Gross Description:

Received fresh labeled with the patient's name and "thymus" consists of thymus (body: 6 x 5 x 2 cm, right lower lobe: 15 x 3.5 x 0.5 cm, left lower pole: 8.5 x 2 x 0.5 cm, right and left upper pole: 5 x 4.5 x 0.3 cm), lung wedge (5 x 2.5 x 1.5 cm), pleura (3 x 2 cm), and pericardium (3 x 2.5 cm). The specimen is designated by the surgeon as follows: black stitch: upper pole, double short black stitch: area of tumor against an open pleural space (inked orange), blue single stitch: where phrenic nerve was dissected off (inked purple), white stitch: mediastinal pleura (inked blue). The rest of the specimen is inked as follows: anterior-yellow, posterior-black, patch of pericardium-green, patch of innominate vein-blue, 7 cm long staple line-red. The specimen is serially sectioned from superior to inferior (medial to lateral plane) to reveal a 3.5 x 3 x 2 cm ill-defined white lesion which appears to abut the pleura, pericardium and lung resection margin. Representative sections are submitted as follows:

cassette 1=tumor to lung, open pleura
cassette 2=?separate nodule to anterior-posterior margin
cassette 3&4=tumor to lung, open pleura, pericardium
cassette 5=pericardium, anterior aspect
cassette 6&7=tumor to lung, pericardium, anterior mediastinal pleura
cassette 8&9=tumor to phrenic nerve, pericardium
cassette 10&11=tumor to mediastinal pleura, open pleural space, posterior aspect ?separate nodule in cassette 11
cassette 12&13=tumor to innominate vein
cassette 14=representative section of superior pole
cassette 15=representative section of the right lower pole
cassette 16=representative section of the left lower pole

Summary of Stains Performed and Reviewed

	Count
Keratin, AE1/AE3 PK *	2
Negative Control *	2

*The immunohistochemical profile may include the use of Analyte Specific Reagents, or Research Agents, whose performance characteristics have not been established by the supplier. The histochemical tests were developed and their performance characteristics were determined by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary for this test. These tests are used for clinical purposes and should not be regarded as investigational or for research. This laboratory is regulated under the Clinical Laboratory Improvements Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing. External and Internal controls stained appropriately.

Summary of Tissue Submitted for Microscopic Examination

Block Detail

	# Blocks	Designation	#	Description
Part 1] THYMUS	16	[Undes]	(16)	(No Description)

Printed by:

END OF REPORT

Source: NCI Genomic Data Commons file da8dbe1d-67c1-4854-8c08-d2669a7a0af3 (TCGA-4X-A9F9.F32A3080-CA80-496C-B137-41DC46FCE1E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).